Somatic mutation profile of tumor specimen 0DNHH3 from CCDI case PBCBNG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,283 days).
Specimen 0DNHH3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d566fb4b-31c5-410f-b7da-2f644a60d932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNHGR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23fa5ec1-7e1b-4171-a991-e655436e38df

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC3A | c.8356T>G p.C2786G | Missense Mutation (SNP) | VAF 92/517 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- WIPF3 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); called by muse, mutect2
- CAPN15 | c.2859C>T p.A953= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as rs1156692231; called by muse, mutect2, varscan2
- OXTR | c.249C>A p.I83= | Silent (SNP) | VAF 85/321 reads (26%) | called by muse, mutect2, varscan2
- SCEL | c.36A>T p.T12= | Silent (SNP) | VAF 68/644 reads (11%) | called by muse, mutect2, varscan2
